Gene-level copy-number profile of tumor specimen TCGA-EJ-7782-01A from TCGA case TCGA-EJ-7782, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.1 years (25,965 days).
Specimen TCGA-EJ-7782-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.9a9209d3-0ff1-47a5-a3d4-caad8ba732c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7782-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c007c445-aa71-403d-982a-5f3e4ade3d38

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 158; copy number 1: 5,873; copy number 2: 52,071; copy number 3: 1,707.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7782-01A-11D-2112-01): tumor purity 0.75, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 152 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:184,902,111–184,902,562, 1 gene: RPL23AP33.
- chr2:185,547,135–186,509,361, 14 genes: ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr2:186,827,475–186,849,208, 1 gene: ZSWIM2.
- chr5:21,341,833–21,779,522, 5 genes (within-gene range 0–1): GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–21,884,310, 1 gene: HSPD1P1.
- chr5:23,262,159–23,329,892, 4 genes: AC010460.2, Y_RNA, AC010460.3, AC010460.1.
- chr5:23,456,468–23,456,850, 1 gene: AC109445.1.
- chr5:97,504,663–100,153,779, 46 genes (within-gene range 0–1): LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P.
- chr6:67,210,408–67,210,480, 1 gene: AL591004.1.
- chr6:78,604,467–78,606,036, 1 gene: AL121718.1.
- chr6:84,421,028–87,095,106, 44 genes: LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA.
- chr7:57,067,950–57,275,197, 33 genes: AC122133.1, ZNF479, AC099654.11, AC099654.2, AC099654.5, AC099654.8, MTATP6P8, MTCO3P10, AC099654.4, MTND4LP32, MTND4P4, MTND5P6, MTND6P29, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, AC099654.6, MTATP6P10, MTCO3P4, AC099654.9, AC099654.7, MTND4P5, MTND5P7, AC099654.10, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.12, AC099654.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
